Somatic mutation profile of tumor specimen 0DLRHR from CCDI case PBBYID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (730 days).
Specimen 0DLRHR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d545f818-b59a-49bc-baad-08d2844fa308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccccf59e-8500-43a7-88fa-6472d234eb12

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 391/776 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, varscan2
- APC2 | c.3369C>T p.P1123= | Silent (SNP) | VAF 62/304 reads (20%) | catalogued as rs758399348; called by muse, varscan2
- CALU | c.*2896_*2911del | 3'UTR (DEL) | VAF 10/88 reads (11%) | catalogued as rs553708996; called by pindel, varscan2
